Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A88Z, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A88Z-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3
Carcinoma, squamous cell NOS
8070/3
Site ^{CCK} Middle third of esophagus C15.4
Distal third of esophagus C15.5
JW 11/12/13

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

-year-old female with squamous cell esophageal cancer. Operative procedure:
THE transhiatal esophagectomy jejunostomy.

PROCEDURE:

VERIFIED BY:

1. "Esophageal margin closed end is distal, opened end proximal" A 1.7 x 1.4 x 0.7 cm segment of pink-red esophagus with staple line at one end.

1A. Proximal end.

Frozen section control.

1A. Remainder of specimen. (2 cassettes,

2. "Thoracic esophagus" Received fresh in a medium container is a segment of esophagus (6.5 cm in length and averages 3.0 cm in circumference) and an attached portion of stomach that is 5.0 x 4.0 cm. The serosa of the esophagus is grey-brown and fibrous with a portion of stomach is predominantly surfaced by yellow glistening adipose tissue. There is a 2.5 x 2.0 cm tan-brown centrally ulcerated mass with rolled borders that is 2.3 cm from the proximal margin, 2.0 cm from the GE junction and occupies approximately 95% of the circumference of the esophagus. Sectioning through the mass reveals it to be approximately 0.8 cm thick and grossly abut but not extend through the muscularis propria. Located 1.5 cm proximal to the aforementioned mass is a 0.8 cm in greatest dimension tan nodule that upon sectioning has a tan-white solid cut surface and grossly abuts the muscularis propria. The GE junction and the remaining mucosa is tan and unremarkable with a grey-white area just distal to the first described mass. The GE junction is grossly unremarkable. The mucosa of the stomach is tan, normally folded and grossly unremarkable. Examination of the attached adipose tissue reveals eight probable lymph nodes that range from 0.5 up to 1.5 cm in greatest dimension. The largest possible node is firm and has tan-white, solid cut surfaces.

2A.-E. Mass entirely submitted.

2F. Second described nodule.

2G. Representative section of stomach and distal margin.

2H. Four lymph nodes in their entirety.

2I. Three lymph nodes in their entirety.

2J. One lymph node bisected. (10 cassettes,

FROZEN SECTION REPORT:

1A. Ulcer and inflammation. Negative for carcinoma.

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 3
SEX: F
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

Permanent sections confirm frozen section report.

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Squamous cell carcinoma.

Depth of invasion: Submucosa.

Number of positive lymph nodes: 2/8.

Extranodal metastasis: Unknown. Specify site: _

Pattern of invasion: Expansile.

Esophageal and gastric resection margins involved: No.

Deep resection margin involved: No.

TNM classification: T1 N1 MX

PROCEDURE:

VERIFIED BY:

1.&2. Esophagus and stomach, transhiatal esophagectomy: Invasive squamous cell carcinoma extending to submucosa. Angiolymphatic invasion identified. Two of eight lymph nodes positive for metastatic squamous cell carcinoma. Surgical margins negative. Please see template.

I, _____ the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

Source: NCI Genomic Data Commons file 0a60e6f7-cecf-41a5-b6ff-f57971b63932 (TCGA-L5-A88Z.9B690B5D-2318-4A33-B49B-94CBC5085670.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).